Somatic mutation profile of tumor specimen C3N-04098-01 (aliquot CPT0285540007) from CPTAC case C3N-04098, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.2 years (23,078 days).
Specimen C3N-04098-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cff6e894-a1be-4a12-970c-bba7d054b4a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04098-31 (Blood Derived Normal), aliquot CPT0285570002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acf771f5-4b0a-43c5-bf4e-c8f6b1e65211

The open-access MAF lists 101 somatic variants for this specimen: 65 protein-altering or splice-affecting, 30 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 30, Nonsense Mutation 6, 3'UTR 2, Splice Region 2, Frame Shift Del 2, 3'Flank 1, In Frame Del 1, RNA 1, Intron 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 21/224 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121918453, CM013418, CM090463, COSV61004775, COSV61004869, COSV61006317; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ANK1 | c.5314C>T p.Q1772* | Nonsense Mutation (SNP) | VAF 31/285 reads (11%) | catalogued as CM156164, COSV55880982; called by muse, mutect2, varscan2
- BASP1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs1174816224, COSV59474031; called by muse, mutect2
- CARD10 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 139/180 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1363325325; called by muse, mutect2, varscan2
- CD3D | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 144/382 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs375444192; called by muse, varscan2
- CNGA2 | c.1357C>T p.R453C | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs755787323, COSV61703700, COSV61705041; called by muse, mutect2, varscan2
- DOCK5 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs190951623, COSV99377562; called by muse, mutect2, varscan2
- FAM83B | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1333653079; called by muse, mutect2, varscan2
- GAD2 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 60/88 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as rs762107590; called by muse, mutect2, varscan2
- GJA10 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551586993, COSV65356565; called by muse, mutect2, varscan2
- GPR32 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 104/404 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); catalogued as rs746445364, COSV54513842, COSV54514973; called by muse, mutect2, varscan2
- GRHL3 | c.362C>G p.P121R (on ENST00000350501 / NM_198174.3; = p.P126R on NM_021180.3) | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.084); catalogued as COSV52569802; called by muse, mutect2, varscan2
- HTR1E | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as rs780937683, COSV59509592; called by muse, mutect2, varscan2
- IGHMBP2 | c.2035C>T p.R679W | Missense Mutation (SNP) | VAF 62/155 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.27); catalogued as rs371157210; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INPP5D | c.1902G>A p.E634= (on ENST00000445964 / NM_001017915.3; = p.E633= on NM_005541.5) | Splice Region (SNP) | VAF 81/123 reads (66%) | catalogued as rs191364364; called by muse, mutect2, varscan2
- ITGB1BP1 | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 68/226 reads (30%) | catalogued as rs368082222; called by muse, mutect2, varscan2
- LFNG | c.375C>A p.F125L | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV56069101; called by muse, mutect2, varscan2
- MAMDC4 | c.2820+3G>A | Splice Region (SNP) | VAF 49/106 reads (46%) | catalogued as rs761853760; called by muse, mutect2, varscan2
- MUC16 | c.31469C>A p.S10490Y | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs780052125, COSV67481028; called by muse, mutect2, varscan2
- MYLK | c.3902G>A p.R1301H | Missense Mutation (SNP) | VAF 205/470 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as rs770980369, COSV100658752; called by muse, mutect2, varscan2
- NPY1R | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.984); catalogued as rs370691271; called by muse, mutect2, varscan2
- ODF2 | c.1115G>A p.R372H (on ENST00000434106 / NM_153433.2; = p.R348H on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.378); catalogued as rs775525425; called by muse, mutect2, varscan2
- PLCE1 | c.6508T>G p.C2170G | Missense Mutation (SNP) | VAF 110/165 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); catalogued as rs769544936; called by muse, mutect2, varscan2
- PRR33 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 173/435 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs763498026; called by muse, mutect2, varscan2
- SBF2 | c.2881C>T p.Q961* | Nonsense Mutation (SNP) | VAF 95/258 reads (37%) | catalogued as COSV56294403; called by muse, mutect2, varscan2
- SEMA3F | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 106/282 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs1045993195, COSV50028423; called by muse, mutect2, varscan2
- SERPINB10 | c.771C>A p.D257E | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.019); catalogued as rs1426950334, COSV53073406; called by muse, mutect2, varscan2
- SLC9A4 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 118/270 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs754982353, COSV54839342; called by muse, mutect2, varscan2
- SOX10 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 149/202 reads (74%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as rs1447194601; called by muse, mutect2, varscan2
- STYXL1 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.723); catalogued as rs781959500, COSV50388321; called by muse, mutect2, varscan2
- TAS2R46 | c.105G>A p.W35* | Nonsense Mutation (SNP) | VAF 99/259 reads (38%) | catalogued as rs1317047705, COSV67860852; called by muse, mutect2, varscan2
- TKTL1 | c.373A>G p.S125G | Missense Mutation (SNP) | VAF 57/142 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782226756, COSV54213813; called by muse, mutect2, varscan2
- TLCD3B | c.28dup p.V10Gfs*59 | Frame Shift Ins (INS) | VAF 16/36 reads (44%) | catalogued as rs780301705; called by mutect2, varscan2
- TMEM255B | c.149C>T p.T50M | Missense Mutation (SNP) | VAF 95/131 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200265697, COSV64703434; called by muse, mutect2, varscan2
- TRIM72 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0.235); catalogued as rs1448803842; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 56/221 reads (25%) | catalogued as COSV66023155; called by muse, mutect2, varscan2
- ABRAXAS1 | c.655_658del p.Y219Lfs*7 | Frame Shift Del (DEL) | VAF 22/80 reads (28%) | called by mutect2, pindel, varscan2
- ALDH1B1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ANK2 | c.10523G>A p.S3508N | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- CECR2 | c.2849C>T p.P950L (on ENST00000342247 / NM_001290047.2; = p.P767L on NM_001290046.1) | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CREB1 | c.605A>G p.Q202R (on ENST00000432329 / NM_134442.5; = p.Q188R on NM_004379.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 84/222 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DCTN5 | c.517T>C p.Y173H | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DLG2 | c.230T>C p.V77A (on ENST00000650630 / NM_001351274.2; = p.V40A on NM_001142699.3) | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- DNAH6 | c.11019_11021del p.S3674del | In Frame Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- DNAH7 | c.5939C>G p.T1980S | Missense Mutation (SNP) | VAF 14/277 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- EML5 | c.1668del p.F556Lfs*11 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel, varscan2
- EPB41L3 | c.2926C>T p.P976S | Missense Mutation (SNP) | VAF 114/306 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA4L | c.1397A>G p.N466S | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MAGEA8 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHGC5 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PLD4 | c.130T>A p.S44T | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- PLEKHG2 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 111/407 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- POU2F3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- QSER1 | c.2655T>G p.D885E (on ENST00000399302; = p.D1014E on NM_001076786.3) | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SAFB | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 114/497 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SKIDA1 | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 102/141 reads (72%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC4A9 | c.1892C>A p.S631Y (on ENST00000507527 / NM_001258428.2; = p.S607Y on NM_031467.3) | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A4 | c.944T>C p.L315S | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SMARCA5 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- STON2 | c.2789C>T p.T930I (on ENST00000649389 / NM_001366849.2; = p.T873I on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); called by muse, mutect2
- SYT10 | c.810T>A p.Y270* | Nonsense Mutation (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- TTN | c.41056C>A p.R13686S (on ENST00000591111; = p.R6262S on NM_003319.4) | Missense Mutation (SNP) | VAF 18/49 reads (37%) | PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- XKR5 | c.1087T>A p.S363T | Missense Mutation (SNP) | VAF 126/298 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZFPL1 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 177/414 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZSCAN23 | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 88/461 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ACVR2B | c.390G>A p.P130= | Silent (SNP) | VAF 55/149 reads (37%) | catalogued as rs149064170; called by muse, mutect2, varscan2
- ADAMTS20 | c.360C>T p.D120= | Silent (SNP) | VAF 37/171 reads (22%) | catalogued as rs369135962; called by muse, mutect2, varscan2
- BEND2 | c.1080C>T p.N360= | Silent (SNP) | VAF 73/211 reads (35%) | called by muse, mutect2, varscan2
- CACNA2D4 | c.2022G>A p.L674= | Silent (SNP) | VAF 96/262 reads (37%) | catalogued as COSV99765857; called by muse, mutect2, varscan2
- CEACAM21 | c.87C>T p.N29= | Silent (SNP) | VAF 165/568 reads (29%) | catalogued as rs545179785, COSV51815274; called by muse, mutect2, varscan2
- EPHB6 | c.1302C>T p.F434= | Silent (SNP) | VAF 70/805 reads (9%) | catalogued as rs950848585, COSV67420134; called by muse, mutect2
- FBLN2 | c.2142C>T p.G714= | Silent (SNP) | VAF 71/172 reads (41%) | catalogued as COSV99853042; called by muse, mutect2, varscan2
- FLT4 | c.2256C>T p.N752= | Silent (SNP) | VAF 108/229 reads (47%) | catalogued as rs986151831, COSV56112283; called by muse, mutect2, varscan2
- GPC3 | c.1188G>A p.K396= | Silent (SNP) | VAF 112/296 reads (38%) | called by muse, mutect2, varscan2
- HDAC3 | c.354G>A p.L118= | Silent (SNP) | VAF 117/296 reads (40%) | catalogued as rs1250159790; called by muse, mutect2, varscan2
- IRS4 | c.1173C>T p.D391= | Silent (SNP) | VAF 232/565 reads (41%) | catalogued as COSV64534667; called by muse, mutect2, varscan2
- KCNC4 | c.996C>T p.S332= | Silent (SNP) | VAF 112/288 reads (39%) | catalogued as rs376805682; called by muse, mutect2, varscan2
- KEL | c.1605C>A p.S535= | Silent (SNP) | VAF 40/502 reads (8%) | catalogued as COSV100787012; called by muse, mutect2
- MYT1L | c.1668C>T p.R556= | Silent (SNP) | VAF 39/98 reads (40%) | catalogued as rs779305136; called by muse, mutect2, varscan2
- NEU3 | c.606G>T p.L202= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- NPAS2 | c.420A>G p.E140= | Silent (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.8635C>A p.R2879= | Silent (SNP) | VAF 32/50 reads (64%) | catalogued as COSV101006194; called by muse, mutect2, varscan2
- PSG8 | c.525C>T p.D175= | Silent (SNP) | VAF 185/618 reads (30%) | catalogued as rs143424985, COSV60613068; called by muse, mutect2, varscan2
- PUS7 | c.1035C>T p.F345= | Silent (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- RFPL4A | c.468C>T p.D156= | Silent (SNP) | VAF 275/1159 reads (24%) | catalogued as rs1307623235; called by muse, mutect2, varscan2
- RSPH10B | c.171C>G p.P57= | Silent (SNP) | VAF 158/1074 reads (15%) | catalogued as rs777347060; called by muse, mutect2, varscan2
- SHANK2 | c.858C>T p.H286= | Silent (SNP) | VAF 84/639 reads (13%) | catalogued as rs782463740; called by muse, mutect2, varscan2
- SLC6A8 | c.255C>T p.N85= | Silent (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- SYT14 | c.168C>T p.G56= | Silent (SNP) | VAF 49/110 reads (45%) | catalogued as rs540332386, COSV55055602; called by muse, mutect2, varscan2
- TGM6 | c.1158C>T p.H386= | Silent (SNP) | VAF 220/677 reads (32%) | catalogued as rs371763464; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRPV6 | c.426C>G p.A142= | Silent (SNP) | VAF 116/447 reads (26%) | catalogued as COSV100844508; called by muse, mutect2, varscan2
- VSTM1 | c.78G>A p.P26= | Silent (SNP) | VAF 61/191 reads (32%) | catalogued as rs143258264; called by muse, mutect2, varscan2
- ZNF629 | c.1536C>T p.N512= | Silent (SNP) | VAF 108/281 reads (38%) | called by muse, mutect2, varscan2
- ZNF727 | c.267C>T p.H89= | Silent (SNP) | VAF 33/100 reads (33%) | catalogued as rs761761791, COSV70702122; called by muse, mutect2, varscan2
- ZSWIM8 | c.3402T>A p.P1134= (on ENST00000605216 / NM_001242487.2; = p.P1139= on NM_015037.3) | Silent (SNP) | VAF 8/89 reads (9%) | catalogued as COSV100013601; called by muse, mutect2
- ACAD9 | c.*261G>A | 3'UTR (SNP) | VAF 148/362 reads (41%) | called by muse, mutect2, varscan2
- DNASE1L1 | chrX:154412057 G>A | 5'Flank (SNP) | VAF 147/351 reads (42%) | catalogued as rs1465488296; called by muse, mutect2, varscan2
- KDM3A | c.*13T>C | 3'UTR (SNP) | VAF 49/106 reads (46%) | catalogued as rs749498022, COSV100460874; called by muse, mutect2, varscan2
- MIR205 | chr1:209432275 G>A | 3'Flank (SNP) | VAF 176/435 reads (40%) | catalogued as rs374711212; called by muse, mutect2, varscan2
- OR2A13P | n.840G>C | RNA (SNP) | VAF 68/328 reads (21%) | catalogued as rs756320483; called by muse, varscan2
- SLCO1B3-SLCO1B7 | c.1866-23830T>C | Intron (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
